Somatic mutation profile of tumor specimen TCGA-J8-A3O2-06A (aliquot TCGA-J8-A3O2-06A-11D-A23M-08) from TCGA case TCGA-J8-A3O2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.3 years (14,339 days).
Specimen TCGA-J8-A3O2-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb9fecbf-1ae7-4646-aa42-606f20152239.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A3O2-10A (Blood Derived Normal), aliquot TCGA-J8-A3O2-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bc28c82-ecc2-43b0-93d4-01ef127e753f

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CLSTN3 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.129); catalogued as rs369161461; called by muse, mutect2, varscan2
- FHOD3 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs780516974, COSV99941396, COSV99943362; called by muse, varscan2
- FOXD2 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100599255; called by muse, mutect2, varscan2
- GBA2 | c.355T>G p.L119V | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100960237; called by muse, mutect2, varscan2
- PPP1R9B | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100380734; called by muse, mutect2, varscan2
- S100PBP | c.391A>T p.K131* | Nonsense Mutation (SNP) | VAF 35/91 reads (38%) | catalogued as COSV100758359; called by muse, mutect2, varscan2
- SOGA1 | c.1549C>T p.Q517* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99414179; called by muse, mutect2, varscan2
- YBX2 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 187/430 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1269226333, COSV99142729; called by muse, mutect2, varscan2
- BTD | c.1023T>C p.F341= | Silent (SNP) | VAF 94/200 reads (47%) | catalogued as COSV100329618; called by muse, mutect2, varscan2
- C1orf162 | c.297C>G p.A99= | Silent (SNP) | VAF 60/185 reads (32%) | catalogued as COSV100636220; called by muse, mutect2, varscan2
- SNTA1 | c.1275G>A p.V425= | Silent (SNP) | VAF 14/169 reads (8%) | catalogued as COSV99458759; called by muse, mutect2
